FM case AD492 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms.
https://portal.gdc.cancer.gov/cases/c0a7e975-90ba-40bb-ac10-8ab27a11c7d0

Male, 57.5 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3). Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
